Somatic mutation profile of tumor specimen ALCH-B04N-TTP1-A (aliquot ALCH-B04N-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B04N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,692 days).
Specimen ALCH-B04N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df3c97f3-ef43-4a81-83f6-c57b04c27b52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B04N-NB1-A (Blood Derived Normal), aliquot ALCH-B04N-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c03747a8-51d2-4b43-807a-471e173c1660

The open-access MAF lists 158 somatic variants for this specimen: 110 protein-altering or splice-affecting, 31 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 31, Intron 7, Nonsense Mutation 6, RNA 5, Splice Site 4, 3'UTR 3, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 67/399 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNKSR2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759498814, COSV54249894; ClinVar: benign; called by muse, mutect2, varscan2
- DCAKD | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.078); catalogued as rs141495277; called by muse, mutect2
- DCX | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs758499194, COSV57571264; called by muse, mutect2, varscan2
- DNAJB2 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV60677912; called by muse, mutect2
- FAM47A | c.1770C>A p.S590R | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV60496154; called by muse, mutect2, varscan2
- FAM83B | c.1111G>C p.A371P | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60926869; called by muse, mutect2, varscan2
- FAT3 | c.10644G>T p.K3548N | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs79935398; called by muse, mutect2
- GPR39 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 36/365 reads (10%) | catalogued as COSV100258666; called by muse, varscan2
- IGKV1D-16 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 101/674 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs375652808; called by muse, mutect2, varscan2
- IRS2 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs753831518, COSV101018805; called by mutect2, varscan2
- ITPRID1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs187352726, COSV100085569; called by muse, mutect2
- LCN8 | c.161G>T p.R54L (on ENST00000612714 / NM_001345934.1; = p.R31L on NM_178469.3) | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100293219; called by muse, mutect2, varscan2
- MROH2B | c.1752G>C p.K584N | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101270502; called by muse, mutect2, varscan2
- MUC16 | c.11753C>T p.T3918M | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as rs139575624, COSV67454508; called by mutect2, varscan2
- NPY2R | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as COSV61527659; called by muse, mutect2, varscan2
- NRXN3 | c.1130C>G p.S377W (on ENST00000335750 / NM_001330195.2; = p.S4W on NM_004796.6) | Missense Mutation (SNP) | VAF 31/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59716282; called by muse, mutect2
- NYAP1 | c.1755G>T p.M585I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as COSV55721329; called by muse, mutect2, varscan2
- OR11L1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 33/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750617036, COSV63314536; called by muse, mutect2
- OR2F1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV67332031; called by muse, mutect2
- OR2M3 | c.679C>A p.H227N | Missense Mutation (SNP) | VAF 48/645 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV71759000, COSV71759041; called by muse, mutect2
- OR5D18 | c.707G>C p.R236P | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV61736494; called by muse, mutect2, varscan2
- PRG3 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs897769972, COSV54663951; called by muse, mutect2, varscan2
- SBNO2 | c.3995C>T p.A1332V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs774638900, COSV100684166; called by muse, mutect2
- SEMA4A | c.559G>T p.V187F | Missense Mutation (SNP) | VAF 40/631 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV61772390; called by muse, mutect2
- SLC16A6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs782727087, COSV59177300; called by muse, mutect2
- SNX2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.82); catalogued as rs865871409; called by muse, mutect2, varscan2
- TCHH | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100914862; called by muse, mutect2, varscan2
- TMC1 | c.1372A>T p.I458F | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1159862966; called by muse, mutect2
- TRIM41 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs772110248, COSV59320083; called by muse, mutect2
- UGT2A3 | c.1342C>A p.H448N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52360809; called by muse, mutect2
- ZNF514 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs149293755; called by muse, mutect2, varscan2
- ZNF665 | c.329G>A p.G110E (on ENST00000600412; = p.G175E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV67218079; called by muse, mutect2, varscan2
- ACTN2 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- AMTN | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2
- ANKRD18B | c.2605A>T p.T869S | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ANKRD34C | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- APC | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- APCDD1L | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.223); called by muse, mutect2
- ARMCX1 | c.245T>A p.L82* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1964G>T p.G655V | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CACNA2D2 | c.2784T>G p.N928K (on ENST00000479441 / NM_001174051.3; = p.N921K on NM_006030.4) | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CALR3 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2
- CCDC9B | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CHAT | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CORIN | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CORIN | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 37/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRTC2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- DCAF5 | c.916A>T p.M306L | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- DEFB116 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 34/443 reads (8%) | called by muse, mutect2
- DEPDC1B | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DGKD | c.3483G>C p.E1161D (on ENST00000264057 / NM_152879.3; = p.E1117D on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- DSG1 | c.2588T>C p.V863A | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- EIF3H | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2
- FAM91A1 | c.889A>G p.K297E | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FARS2 | c.1162A>T p.I388F | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FAT4 | c.10388A>T p.Q3463L | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FN1 | c.2008G>A p.G670S | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR1 | c.796+1G>A p.X266_splice | Splice Site (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- GPR18 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.103); called by muse, mutect2
- INPP4B | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISM1 | c.1188G>T p.R396S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- KCNA2 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KDM4D | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 49/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF14 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KMT2E | c.5485C>T p.Q1829* | Nonsense Mutation (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- KPRP | c.926G>C p.C309S | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KRT5 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 56/612 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- LDB1 | c.1015G>T p.G339W (on ENST00000425280 / NM_001321612.2; = p.G305W on NM_003893.5) | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LINC01548 | n.475-2A>T | Splice Site (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2, varscan2
- LIPI | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- LRP1B | c.4213G>T p.E1405* | Nonsense Mutation (SNP) | VAF 41/266 reads (15%) | called by muse, mutect2, varscan2
- MKRN3 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MRC1 | c.743A>T p.Q248L | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2
- MUC5AC | c.16235C>A p.P5412H | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- MXRA5 | c.4383T>A p.D1461E | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYT1L | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.312); called by muse, mutect2
- NBAS | c.5836G>T p.D1946Y | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- NBAS | c.5835G>T p.K1945N | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- NETO1 | c.1310T>A p.L437Q | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLN | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OR4C15 | c.1001T>C p.L334S (on ENST00000314644; = p.L280S on NM_001001920.2) | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2
- OR4C16 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2
- OR7G3 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- PCDH15 | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 65/782 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHB13 | c.1907C>G p.A636G | Missense Mutation (SNP) | VAF 52/403 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PGK2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- PHIP | c.2123G>T p.S708I | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLCB4 | c.2455G>C p.V819L | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRAMEF19 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 52/1360 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); called by muse, mutect2
- PTPRN | c.2794+2T>G p.X932_splice | Splice Site (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- RASGRP3 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 85/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC24B | c.1166-1G>A p.X389_splice | Splice Site (SNP) | VAF 35/330 reads (11%) | called by muse, mutect2
- SEPTIN7 | c.476A>C p.Q159P | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- SI | c.4837C>A p.H1613N | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A14 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 19/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SOBP | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 27/551 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SYNE2 | c.12337G>T p.A4113S | Missense Mutation (SNP) | VAF 70/721 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2
- TMEM135 | c.268A>T p.R90W | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS15 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 31/451 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- TMTC1 | c.837C>A p.F279L (on ENST00000539277 / NM_001193451.2; = p.F171L on NM_175861.3) | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOGARAM2 | c.902T>A p.I301N | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2
- TPO | c.947A>T p.Q316L | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRIM44 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- USP43 | c.1661A>G p.Q554R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); called by mutect2, varscan2
- WDR11 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 23/463 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZIM3 | c.1187G>C p.C396S | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF134 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF2 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ZNF705B | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 49/600 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANGPT2 | c.228G>A p.S76= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2
- ASPH | c.2034G>T p.P678= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as rs368974538; called by muse, mutect2, varscan2
- ASTN1 | c.1968C>T p.F656= | Silent (SNP) | VAF 24/408 reads (6%) | catalogued as COSV99923454; called by muse, mutect2
- CDH6 | c.2104C>A p.R702= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as rs1429512811, COSV54068715; called by muse, mutect2
- CHAT | c.1203C>T p.T401= | Silent (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- CHRNA1 | c.681G>T p.R227= (on ENST00000261007 / NM_001039523.3; = p.R202= on NM_000079.4) | Silent (SNP) | VAF 36/264 reads (14%) | called by muse, mutect2, varscan2
- DAG1 | c.2580G>A p.A860= | Silent (SNP) | VAF 55/437 reads (13%) | catalogued as rs886044253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH14 | c.10128A>C p.P3376= (on ENST00000445597; = p.P4384= on NM_001367479.1) | Silent (SNP) | VAF 39/284 reads (14%) | catalogued as COSV59895122; called by muse, mutect2, varscan2
- EXOC3L1 | c.885G>A p.A295= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as rs113277538; called by muse, mutect2, varscan2
- FAM71E2 | c.1695C>T p.D565= | Silent (SNP) | VAF 31/338 reads (9%) | catalogued as rs765583549; called by muse, mutect2
- FAT3 | c.11892G>A p.A3964= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV99971343; called by muse, mutect2
- FERMT1 | c.660A>T p.A220= | Silent (SNP) | VAF 75/741 reads (10%) | catalogued as COSV99451206; called by muse, mutect2, varscan2
- GCLM | c.468C>T p.S156= | Silent (SNP) | VAF 34/468 reads (7%) | called by muse, mutect2
- HDAC9 | c.3108C>T p.T1036= (on ENST00000441542 / NM_178425.3; = p.T1033= on NM_178423.3) | Silent (SNP) | VAF 53/393 reads (13%) | catalogued as rs1290980114, COSV101286418, COSV101286738; called by muse, mutect2, varscan2
- LAMA1 | c.6075G>C p.T2025= | Silent (SNP) | VAF 33/273 reads (12%) | catalogued as COSV67534312; called by muse, mutect2, varscan2
- LAMB1 | c.3897G>A p.V1299= | Silent (SNP) | VAF 36/406 reads (9%) | called by muse, mutect2
- LINGO2 | c.624G>T p.L208= | Silent (SNP) | VAF 23/245 reads (9%) | called by muse, mutect2
- LRRC4C | c.1293C>A p.S431= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as rs970904805, COSV53442079; called by muse, mutect2, varscan2
- MTUS1 | c.1296C>T p.V432= | Silent (SNP) | VAF 38/427 reads (9%) | called by muse, mutect2
- MYH7 | c.4428C>T p.S1476= | Silent (SNP) | VAF 45/451 reads (10%) | catalogued as COSV62523044; called by muse, mutect2
- NEK5 | c.1137T>A p.P379= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- OR52N5 | c.528T>A p.P176= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- SOAT2 | c.996C>T p.S332= | Silent (SNP) | VAF 16/211 reads (8%) | called by muse, mutect2
- SPSB2 | c.312C>T p.A104= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs782717258, COSV99222815; called by muse, mutect2, varscan2
- SPTA1 | c.7116C>A p.T2372= | Silent (SNP) | VAF 152/579 reads (26%) | called by muse, mutect2, varscan2
- SYNE2 | c.12336G>C p.L4112= | Silent (SNP) | VAF 68/712 reads (10%) | called by muse, mutect2
- TARM1 | c.702G>A p.S234= (on ENST00000616041 / NM_001330650.1; = p.S226= on NM_001135686.3) | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as rs936939587, COSV71524906; called by muse, mutect2
- TNIK | c.2376A>G p.R792= | Silent (SNP) | VAF 25/284 reads (9%) | catalogued as rs1178283232; called by muse, mutect2
- TPO | c.948G>A p.Q316= | Silent (SNP) | VAF 52/346 reads (15%) | catalogued as rs752430776; called by muse, mutect2, varscan2
- TRANK1 | c.3003A>T p.T1001= | Silent (SNP) | VAF 35/374 reads (9%) | called by muse, mutect2
- ZNF521 | c.402G>A p.K134= | Silent (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824304 C>A | 3'Flank (SNP) | VAF 17/229 reads (7%) | catalogued as rs1400485143; called by muse, mutect2
- BRSK2 | c.*193G>C | 3'UTR (SNP) | VAF 26/488 reads (5%) | catalogued as rs905984226; called by muse, mutect2
- C10orf143 | c.69+3245G>A | Intron (SNP) | VAF 22/446 reads (5%) | called by muse, mutect2
- CRHBP | c.82-17C>A | Intron (SNP) | VAF 48/616 reads (8%) | called by muse, mutect2
- FAM74A3 | n.158G>C | RNA (SNP) | VAF 60/916 reads (7%) | called by muse, mutect2
- GDF6 | c.*39G>T | 3'UTR (SNP) | VAF 15/84 reads (18%) | catalogued as COSV54627655; called by muse, varscan2
- GULP1 | c.843+1839A>C | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- LINC00905 | n.751C>A | RNA (SNP) | VAF 8/142 reads (6%) | catalogued as rs1163242136; called by muse, mutect2
- LINC01630 | n.219+73231C>T | Intron (SNP) | VAF 50/480 reads (10%) | called by muse, mutect2, varscan2
- LINC02054 | n.2373A>T | RNA (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- LRRC7 | c.100+37735_100+37737delinsAA | Intron (DEL) | VAF 9/74 reads (12%) | called by pindel, varscan2*
- MS4A1 | c.*24C>A | 3'UTR (SNP) | VAF 42/394 reads (11%) | called by muse, mutect2
- MYADML | n.602G>T | RNA (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- NBPF22P | n.832C>A | RNA (SNP) | VAF 72/824 reads (9%) | called by muse, mutect2
- PPARA | c.-29G>T | 5'UTR (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2
- ST3GAL3 | c.348-15320G>T | Intron (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- ZNF783 | c.802+3049G>T | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
